CCDI case PBCDPP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a3d7e011-40e9-4afa-9093-352139881b54

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.5 years (3,457 days).

Biospecimens (3 samples)
- Sample 0DPFM8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPFMG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPFMI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
